Somatic mutation profile of tumor specimen TCGA-A7-A4SF-01A (aliquot TCGA-A7-A4SF-01A-11D-A25Q-09) from TCGA case TCGA-A7-A4SF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.7 years (19,985 days).
Specimen TCGA-A7-A4SF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 297580ca-d9bb-4ece-9f61-32ed97812b5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A4SF-10A (Blood Derived Normal), aliquot TCGA-A7-A4SF-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13456867-b85b-4e5a-b6c7-9462abd8e9c2

The open-access MAF lists 83 somatic variants for this specimen: 58 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 22, Frame Shift Del 5, Nonsense Mutation 3, Intron 1, Splice Region 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 44/61 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCB11 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV55592828; called by muse, mutect2, varscan2
- ACBD5 | c.812A>T p.E271V (on ENST00000375888 / NM_001352568.1; = p.E262V on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV65519856; called by muse, mutect2, varscan2
- ACSBG1 | c.69G>C p.E23D | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs374715026, COSV51907153; called by muse, mutect2, varscan2
- ADGRB1 | c.2222T>A p.L741Q | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60097668; called by muse, mutect2, varscan2
- AP2A2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV59960835; called by muse, mutect2, varscan2
- BHMT2 | c.1066C>G p.P356A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV54873226; called by muse, mutect2, varscan2
- CCT3 | c.1345C>A p.R449S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV55289459; called by muse, mutect2, varscan2
- CEACAM4 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.602); catalogued as rs200115429, COSV55731905, COSV99701214; called by muse, mutect2, varscan2
- CFAP65 | c.3637G>A p.V1213M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs149988134; called by muse, mutect2, varscan2
- CHST2 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58885814; called by muse, mutect2, varscan2
- CMYA5 | c.12004G>T p.V4002L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV69745690; called by muse, mutect2, varscan2
- CMYA5 | c.12005T>G p.V4002G | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV69745694; called by muse, mutect2, varscan2
- CNTN4 | c.2811A>G p.K937= | Splice Region (SNP) | VAF 28/55 reads (51%) | catalogued as COSV61874227; called by muse, mutect2, varscan2
- CWF19L1 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as COSV62499355; called by muse, mutect2, varscan2
- CYP2U1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.027); catalogued as rs972710866, COSV60548968; called by muse, mutect2, varscan2
- DPM1 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs1386530462, COSV65373306; called by muse, mutect2, varscan2
- ECD | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV65900087; called by muse, mutect2, varscan2
- EEF1A2 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as COSV53204749; called by muse, mutect2, varscan2
- ELOVL4 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV63954000; called by muse, mutect2, varscan2
- FAM47C | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.583); catalogued as rs149352851, COSV100792276, COSV100792618; called by muse, mutect2, varscan2
- FERMT3 | c.1519G>A p.V507I (on ENST00000279227 / NM_178443.3; = p.V503I on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs769458086, COSV54180507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFAP | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV53651158; called by muse, mutect2, varscan2
- GIGYF2 | c.2143G>T p.D715Y | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV65250214; called by muse, mutect2, varscan2
- GON4L | c.709_710del p.N237* | Frame Shift Del (DEL) | VAF 51/116 reads (44%) | catalogued as COSV55195067; called by mutect2, pindel, varscan2
- GPR55 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411707860, COSV101235771, COSV67407885; called by muse, mutect2, varscan2
- IGSF10 | c.4505T>A p.V1502E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV56786252; called by muse, mutect2, varscan2
- IVL | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV64216371; called by muse, mutect2, varscan2
- LIPH | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV56184370; called by muse, mutect2, varscan2
- LMCD1 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV50087290; called by muse, mutect2, varscan2
- LRRTM1 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54440932, COSV54442487; called by muse, mutect2, varscan2
- LRRTM4 | c.430A>C p.K144Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.214); catalogued as COSV69140467; called by muse, mutect2, varscan2
- LTBP4 | c.1721C>G p.S574C (on ENST00000308370 / NM_001042544.1; = p.S537C on NM_003573.2) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV52582808; called by muse, mutect2, varscan2
- MOSPD2 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.715); catalogued as COSV66860224; called by muse, mutect2, varscan2
- NCOA5 | c.576T>G p.F192L | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV51644944; called by muse, mutect2, varscan2
- OR8H1 | c.470del p.V157Afs*6 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as COSV57294332, COSV57294450; called by mutect2, pindel, varscan2
- PCDHA11 | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV56508767; called by muse, mutect2, varscan2
- PDE1C | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV58515956; called by muse, mutect2, varscan2
- PHLDB1 | c.2554G>C p.D852H | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV61879132; called by muse, mutect2, varscan2
- PHLDB1 | c.2678G>C p.R893T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV61876740, COSV61879139; called by muse, mutect2, varscan2
- PRKACG | c.528C>G p.D176E | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV55249398; called by muse, mutect2, varscan2
- PWWP2A | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61046539; called by muse, mutect2, varscan2
- SELENOP | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV72484717; called by muse, mutect2, varscan2
- SLC24A4 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV54114058; called by muse, mutect2, varscan2
- SPHKAP | c.3473G>A p.S1158N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.081); catalogued as rs1055187571, COSV60881905; called by muse, mutect2, varscan2
- SPHKAP | c.2156T>C p.F719S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV60881920; called by muse, mutect2, varscan2
- SRP68 | c.1166C>G p.S389* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV57162947, COSV57163169; called by muse, mutect2, varscan2
- STAG1 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.515); catalogued as COSV52611801; called by muse, mutect2, varscan2
- TRPM8 | c.2682G>C p.Q894H | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61222316; called by muse, mutect2, varscan2
- UBR1 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV51930666; called by muse, mutect2, varscan2
- ZC3HAV1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1196739916, COSV54295707; called by muse, mutect2, varscan2
- ZMYM3 | c.2214G>C p.Q738H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58738278; called by muse, mutect2, varscan2
- ADCY2 | c.2924A>T p.E975V | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PATJ | c.5322G>T p.M1774I | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- RAB6D | c.76_77del p.K26Dfs*10 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, varscan2
- RUFY2 | c.1727_1739del p.K576Ifs*72 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- TAAR9 | c.376_401del p.I126Yfs*2 | Frame Shift Del (DEL) | VAF 66/298 reads (22%) | called by mutect2, pindel
- ZNF320 | c.1406dup p.Y469* | Nonsense Mutation (INS) | VAF 58/136 reads (43%) | called by mutect2, pindel, varscan2
- ACTA1 | c.897C>T p.N299= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs533868659, COSV64203504; called by muse, mutect2, varscan2
- ADGRA1 | c.591C>T p.S197= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs762913633, COSV101658615; called by muse, varscan2
- C19orf12 | c.438C>T p.A146= (on ENST00000392278 / NM_001031726.3; = p.A135= on NM_031448.6) | Silent (SNP) | VAF 42/187 reads (22%) | catalogued as rs201476706; called by muse, mutect2, varscan2
- CELF1 | c.1248C>T p.D416= (on ENST00000358597 / NM_001376422.1; = p.D412= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs749396102, COSV60112464; called by muse, mutect2, varscan2
- DHX40 | c.1830C>T p.T610= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as rs763466589, COSV52066397, COSV52067714; called by muse, mutect2
- F5 | c.6258G>T p.S2086= | Silent (SNP) | VAF 67/149 reads (45%) | catalogued as COSV63124808; called by muse, mutect2, varscan2
- FCGBP | c.2640C>T p.F880= | Silent (SNP) | VAF 81/166 reads (49%) | catalogued as rs373203794; called by muse, mutect2, varscan2
- FREM2 | c.2799C>A p.V933= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV54840283; called by muse, mutect2, varscan2
- GON4L | c.36A>G p.T12= | Silent (SNP) | VAF 32/206 reads (16%) | catalogued as rs779813087, COSV55195083; called by muse, mutect2, varscan2
- GPR142 | c.270G>A p.G90= | Silent (SNP) | VAF 69/143 reads (48%) | catalogued as COSV59519535; called by muse, mutect2, varscan2
- HLA-DOB | c.168C>T p.F56= | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- IGSF22 | c.840C>T p.S280= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as COSV60035078; called by muse, mutect2
- KIDINS220 | c.747G>A p.T249= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs748788690, COSV56754228; called by muse, mutect2, varscan2
- KIF17 | c.2661C>T p.D887= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as rs754502972, COSV56118245; called by muse, mutect2, varscan2
- LGR6 | c.2133C>T p.Y711= (on ENST00000367278 / NM_001017403.1; = p.Y659= on NM_021636.3) | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as rs931640832, COSV55158571; called by muse, mutect2, varscan2
- PARP1 | c.1965G>A p.L655= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV64690779; called by muse, mutect2, varscan2
- PCDHB6 | c.1341C>A p.P447= | Silent (SNP) | VAF 59/187 reads (32%) | catalogued as COSV50700539; called by muse, mutect2
- PDILT | c.486C>T p.S162= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as rs530716772, COSV56702350; called by muse, mutect2, varscan2
- RP1L1 | c.84C>A p.T28= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV61445594; called by muse, mutect2, varscan2
- TUBA3C | c.975G>A p.P325= | Silent (SNP) | VAF 126/184 reads (68%) | catalogued as rs891518916, COSV68028425; called by muse, mutect2, varscan2
- ZBTB7B | c.1353C>A p.G451= (on ENST00000292176; = p.G485= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as COSV52692969; called by muse, mutect2, varscan2
- ZNF536 | c.948C>T p.I316= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs904079311, COSV62817576, COSV62825609; called by muse, mutect2, varscan2
- DSCR4 | n.314G>C | RNA (SNP) | VAF 26/199 reads (13%) | catalogued as COSV60300463; called by muse, varscan2
- HOXB1 | c.-2G>A | 5'UTR (SNP) | VAF 52/64 reads (81%) | catalogued as rs1234857895, COSV53318529; called by muse, mutect2, varscan2
- NCL | c.1832+103C>T | Intron (SNP) | VAF 21/70 reads (30%) | catalogued as rs764346257, COSV59546293; called by muse, mutect2, varscan2
